Gene-level copy-number profile of tumor specimen C3L-04787-02 from CPTAC case C3L-04787, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-04787-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c663d03f-8594-4262-b05b-262836989201.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04787-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/b8c1ed5d-e10b-49b8-a0a0-a151541b8879

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 86; copy number 1: 13,316; copy number 2: 40,764; copy number 3: 2,717; copy number 4: 574; copy number 5: 600; copy number 6: 67; copy number 7: 152; copy number 8: 93; copy number 9: 16.

Homozygous deletions (total copy number 0; autosomes only): 86 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:14,061–74,163, 3 genes: AC215217.1, AL713922.1, TUBB8.
- chr11:80,321,620–81,556,425, 7 genes: AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, MTND4LP18, MTND6P25.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr12:133,238,335–133,238,549, 2 genes: RNU6-717P, Y_RNA.
- chr22:30,488,902–32,143,272, 73 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 928 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:93,561,741–93,847,150, 1 gene, copy number 6 (within-gene range 1–8): BCAR3.
- chr1:93,846,832–100,178,273, 96 genes, copy number 5–9 (broad region; genes not listed).
- chr1:118,614,333–120,914,238, 52 genes, copy number 5–7 (within-gene range 4–7): PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr4:49,096–3,501,473, 112 genes, copy number 5 (broad region; genes not listed).
- chr4:3,544,555–9,563,950, 152 genes, copy number 5 (broad region; genes not listed).
- chr4:9,583,942–9,584,131, 1 gene, copy number 5: SNRPCP13.
- chr4:11,914,667–15,969,309, 47 genes, copy number 5 (within-gene range 4–5): AC108037.1, LINC02270, RNU6-578P, ECM1P2, AC093809.1, AC007370.2, AC007370.1, HSP90AB2P, RAB28, LINC01097, NKX3-2, LINC01096, BOD1L1, MIR5091, AC006445.2, AC006445.1, LINC01182, AC007126.1, AC095052.1, LINC01085, AC073848.1, AC092546.1, AC006296.3, AC006296.2, AC006296.1, LINC00504, MTND2P31, SNORA63, CPEB2-DT, CPEB2, C1QTNF7-AS1, RN7SKP170, C1QTNF7, AC099550.1, CC2D2A, AC007016.1, AC116651.1, FBXL5, FAM200B, AC114744.2, BST1, AC114744.1, AC005798.1, CD38, HPRT1P1, FGFBP1, FGFBP2.
- chr4:16,160,505–16,397,323, 6 genes, copy number 5: TAPT1, AC108063.1, TAPT1-AS1, RPS21P4, AC006427.1, ZEB2P1.
- chr4:31,997,376–32,228,543, 2 genes, copy number 5: LINC02506, AC097654.1.
- chr4:43,388,157–43,492,543, 3 genes, copy number 5: AC098590.2, AC098590.1, LINC02383.
- chr4:47,431,960–47,838,106, 9 genes, copy number 5: AC107398.3, COMMD8, AC107398.4, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1.
- chr4:54,229,280–55,313,924, 18 genes, copy number 8 (within-gene range 4–8): PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2.
- chr4:55,798,636–58,565,212, 51 genes, copy number 5–8: RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1, RN7SL492P, RN7SL357P, SPINK2, Metazoa_SRP, Y_RNA, REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, SRIP1, AC096725.1, LINC02494, AC019133.1.
- chr4:62,489,495–65,036,017, 19 genes, copy number 5–9: AC074087.1, HMGN1P11, EXOC5P1, AC097491.1, LARP1BP1, AC093730.1, TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1, LINC02232, AC107058.1.
- chr7:73,985,992–75,074,228, 25 genes, copy number 6: AC099398.1, ELN, ELN-AS1, LIMK1, EIF4H, MIR590, LAT2, RFC2, CLIP2, GTF2IRD1, RNA5SP233, AC211433.2, AC211433.3, GTF2I, AC211433.1, PHBP15, NCF1, GTF2IRD2, STAG3L2, PMS2P5, Y_RNA, SPDYE12P, CASTOR2, RCC1L, Metazoa_SRP.
- chr7:75,769,533–75,823,356, 2 genes, copy number 6: CCL26, CCL24.
- chr7:77,798,792–79,453,667, 17 genes, copy number 7–8 (within-gene range 2–11): PHTF2, Y_RNA, AC004990.1, MAGI2, AC004808.2, AC004808.1, RPL13AP17, AC006043.1, AC007237.1, MAGI2-AS1, MAGI2-AS2, RNU6-337P, AC006355.1, AC006355.2, AC074024.1, RNU6-530P, AC004945.1.
- chr12:130,396,137–131,141,469, 23 genes, copy number 5: RIMBP2, AC063926.1, AC063926.3, AC063926.2, AC095350.1, AC073912.3, STX2, AC073912.1, AC073912.2, RNU6-1077P, RAN, Y_RNA, ADGRD1, AC073862.3, AC073862.4, AC073862.5, AC073862.1, AC073862.2, AC078925.4, ADGRD1-AS1, AC078925.2, AC078925.3, AC078925.1.
- chr22:35,738,736–42,369,284, 269 genes, copy number 5–7 (broad region; genes not listed).
- chr22:42,835,412–43,892,013, 23 genes, copy number 5–7 (within-gene range 4–7): PACSIN2, AL049758.1, TTLL1-AS1, TTLL1, AL022237.1, BIK, MCAT, TSPO, TTLL12, SCUBE1, SCUBE1-AS2, Z82214.1, SCUBE1-AS1, LINC01639, MPPED1, BX546033.1, EFCAB6-AS1, EFCAB6, Z97055.1, HMGN2P9, Z97055.2, SULT4A1, PNPLA5.

Autosomal genes at a single copy (total copy number 1): 13,316. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
